Somatic mutation profile of tumor specimen MP2PRT-PARGSB-TMP1-B (aliquot MP2PRT-PARGSB-TMP1-B-1-0-D-A834-36) from MP2PRT case MP2PRT-PARGSB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,652 days).
Specimen MP2PRT-PARGSB-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3655947-a8ed-42dd-8ce7-ad03d90d27e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGSB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGSB-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3953500c-1a9b-4337-911e-cb56b91c10ee

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 8, Nonsense Mutation 2, RNA 1, Intron 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 194/456 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as COSV101002033, COSV65892039; called by muse, mutect2, varscan2
- ADCY3 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs1268566357; called by muse, mutect2, varscan2
- ATL3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 178/611 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs375618827, COSV60297119; called by muse, mutect2, varscan2
- KIF25 | c.1105C>T p.R369* (on ENST00000354419 / NM_030615.2; = p.R317* on NM_005355.3) | Nonsense Mutation (SNP) | VAF 227/744 reads (31%) | catalogued as rs778957588, COSV63027387; called by muse, mutect2, varscan2
- LRFN5 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 97/553 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs1251897481, COSV53242887; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- AMBRA1 | c.587_590del p.L196Qfs*19 | Frame Shift Del (DEL) | VAF 40/306 reads (13%) | called by mutect2, pindel, varscan2
- FEZ2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- KPNA1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- SCN1A | c.3448A>C p.S1150R (on ENST00000303395 / NM_001202435.3; = p.S1139R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TSPAN8 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 51/636 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- AARS2 | c.819G>C p.L273= | Silent (SNP) | VAF 110/769 reads (14%) | called by muse, mutect2, varscan2
- C11orf87 | c.75C>T p.P25= | Silent (SNP) | VAF 107/793 reads (13%) | called by muse, mutect2, varscan2
- CFAP46 | c.3768C>T p.G1256= | Silent (SNP) | VAF 187/597 reads (31%) | catalogued as rs567316998; called by muse, mutect2, varscan2
- GRIA3 | c.2421C>T p.S807= | Silent (SNP) | VAF 58/363 reads (16%) | catalogued as rs762322961, COSV99990280; called by muse, varscan2
- LGI1 | c.1668C>T p.S556= | Silent (SNP) | VAF 30/272 reads (11%) | catalogued as rs763654125, COSV65058456; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5D13 | c.741G>T p.L247= | Silent (SNP) | VAF 83/536 reads (15%) | catalogued as COSV62332737; called by muse, mutect2, varscan2
- PGD | c.810C>T p.S270= | Silent (SNP) | VAF 170/374 reads (45%) | catalogued as rs773445767, COSV54623083; called by muse, mutect2, varscan2
- RARA | c.516C>T p.P172= | Silent (SNP) | VAF 99/620 reads (16%) | catalogued as rs543538391, COSV54193305; called by muse, mutect2, varscan2
- FAM153CP | n.206G>A | RNA (SNP) | VAF 21/316 reads (7%) | catalogued as rs770769004; called by muse, mutect2, varscan2
- GP6 | c.*329A>C | 3'UTR (SNP) | VAF 78/328 reads (24%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-21058C>T | Intron (SNP) | VAF 82/311 reads (26%) | called by muse, mutect2, varscan2
